Somatic mutation profile of tumor specimen ALCH-B0BT-TTP1-A (aliquot ALCH-B0BT-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0BT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,796 days).
Specimen ALCH-B0BT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20b8c9b6-3eca-44cd-acf6-2740a128c09e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0BT-NB1-A (Blood Derived Normal), aliquot ALCH-B0BT-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bda3b0f-a44a-42e5-b92c-04a1d8df880b

The open-access MAF lists 185 somatic variants for this specimen: 124 protein-altering or splice-affecting, 39 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 39, Nonsense Mutation 10, Intron 9, RNA 9, Splice Site 2, 5'UTR 2, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 24/94 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434569, CM054664, COSV51765492; ClinVar: drug response / likely pathogenic / pathogenic / protective; called by muse, mutect2, varscan2
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 71/274 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/131 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 44/175 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH7 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs773461976; called by muse, mutect2, varscan2
- AGO4 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1287473205; called by muse, mutect2, varscan2
- ANK3 | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs368634935; called by muse, mutect2, varscan2
- ANO5 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100201360; called by muse, mutect2, varscan2
- BRINP3 | c.1369C>A p.R457S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100818882, COSV66516744; called by muse, mutect2, varscan2
- CLTCL1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54233688, COSV54239260; called by muse, mutect2, varscan2
- CNTNAP4 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1170966719, COSV56669709; called by muse, mutect2, varscan2
- CTNNA2 | c.1958C>A p.T653K | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV100559551; called by muse, mutect2, varscan2
- FLRT2 | c.809C>G p.T270R | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs1049827519; called by muse, mutect2
- FSIP2 | c.3252dup p.L1085Tfs*5 | Frame Shift Ins (INS) | VAF 8/78 reads (10%) | catalogued as rs1559025750; called by mutect2, pindel
- GSN | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs756193920; called by muse, mutect2, varscan2
- HMCN1 | c.11653G>C p.D3885H | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54927080; called by muse, mutect2, varscan2
- HRNR | c.8090A>G p.H2697R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs778287887; called by muse, mutect2, varscan2
- INSL3 | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.239); catalogued as rs1475007335; called by muse, mutect2, varscan2
- LVRN | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV63496555; called by muse, mutect2, varscan2
- LYZL2 | c.533A>T p.H178L (on ENST00000375318; = p.H132L on NM_183058.3) | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV64684583; called by muse, mutect2
- MAGI2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62633287; called by muse, mutect2, varscan2
- MED13L | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 45/240 reads (19%) | catalogued as COSV56116702; called by muse, mutect2, varscan2
- MPZL1 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV63256108; called by muse, mutect2, varscan2
- MTUS2 | c.2603C>A p.S868Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54995207; called by muse, mutect2, varscan2
- MYO7B | c.4445C>T p.S1482L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs1291756666, COSV67349545; called by muse, mutect2, varscan2
- NANOG | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV57552003; called by muse, mutect2
- NPAS4 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.189); catalogued as rs1409677021; called by muse, mutect2, varscan2
- OR11L1 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100869508, COSV63315737; called by muse, mutect2, varscan2
- OR4A5 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs760137860, COSV100157359; called by muse, mutect2, varscan2
- OR52W1 | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs372545645; called by muse, mutect2, varscan2
- OR5AP2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs564090082, COSV57257559; called by muse, mutect2, varscan2
- PCDH15 | c.4572G>T p.M1524I (on ENST00000644397 / NM_001354429.2; = p.M1473I on NM_001142769.3) | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as COSV64707187; called by muse, mutect2
- PCLO | c.9455C>T p.T3152M | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs188499676, COSV100433354; called by muse, mutect2, varscan2
- PLA2G15 | c.986A>C p.H329P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54723194, COSV99547344; called by muse, mutect2, varscan2
- RGPD4 | c.4762G>C p.V1588L | Missense Mutation (SNP) | VAF 23/377 reads (6%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); catalogued as rs1164474301; called by muse, mutect2
- RYR2 | c.7241G>T p.G2414V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63672323, COSV63680255; called by muse, mutect2, varscan2
- SHANK3 | c.4073C>G p.S1358C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53182867; called by muse, mutect2, varscan2
- SHB | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100891868; called by muse, mutect2, varscan2
- SLC9A7 | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV60378509; called by muse, mutect2, varscan2
- SORCS1 | c.2741G>T p.W914L | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as COSV53847543, COSV53881351; called by muse, mutect2
- TINAG | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV52510147; called by muse, mutect2, varscan2
- TRIM9 | c.2065G>T p.V689L | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53612814; called by muse, mutect2
- WDFY3 | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as rs1236901064; called by muse, mutect2
- ZNF536 | c.1864G>T p.G622C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1276948635; called by muse, mutect2, varscan2
- ZNF610 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1172046862; called by muse, mutect2, varscan2
- ACRBP | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- ADAM19 | c.1046A>T p.H349L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRA1 | c.953G>C p.S318T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); called by muse, mutect2
- AFF4 | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- AKR1B15 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO2 | c.1588G>T p.G530C (on ENST00000356134 / NM_001278597.3; = p.G534C on NM_001278596.3) | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ATR | c.5239G>C p.G1747R | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C12orf42 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- C4orf54 | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C5orf34 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C6orf201 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CACNA1B | c.3277G>T p.V1093F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by mutect2, varscan2
- CACNA2D4 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CALCR | c.600C>A p.H200Q (on ENST00000649521 / NM_001164737.2; = p.H184Q on NM_001742.4) | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD300LG | c.784_808del p.A262Tfs*26 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- CD86 | c.64+3A>G | Splice Region (SNP) | VAF 30/114 reads (26%) | called by mutect2, varscan2
- CDH8 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDKN2A | c.294_324del p.H98Qfs*38 | Frame Shift Del (DEL) | VAF 21/121 reads (17%) | called by mutect2, pindel
- CLEC9A | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CNPY1 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- CYB5D2 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DDX60 | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.1100A>G p.N367S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELP1 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA6 | c.2816C>A p.P939Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EVC2 | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- F13B | c.500A>T p.Q167L | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FBN3 | c.1325A>G p.D442G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- FRMD6 | c.1570G>T p.D524Y (on ENST00000344768 / NM_001267046.2; = p.D516Y on NM_152330.4) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GIMAP8 | c.265C>G p.L89V | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GORAB | c.975G>C p.E325D | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.616); called by muse, mutect2
- GRID1 | c.728C>A p.A243D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM3 | c.1322C>A p.T441K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.066); called by muse, varscan2
- GUCY1A2 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HDAC4 | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- HNRNPF | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- IL23R | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNT1 | c.2629A>T p.M877L (on ENST00000488444; = p.M896L on NM_020822.3) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.015); called by muse, varscan2
- KCNU1 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- KIAA1549L | c.1657G>T p.G553* (on ENST00000321505; = p.G850* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- KLHL9 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- LRCH2 | c.2166G>T p.L722F | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- LRP1 | c.1181T>A p.V394E | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LRRC32 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NBAS | c.2933C>A p.P978Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NIN | c.4133G>C p.R1378T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- NLRP13 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- NPC1L1 | c.3022T>A p.F1008I | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OLFM4 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.216); called by muse, mutect2
- OR4C11 | c.529T>A p.C177S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52K2 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- PAX6 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PKD1L1 | c.6268G>T p.V2090F | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PNPLA8 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2
- PRSS23 | c.479G>C p.C160S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAG1 | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RALGAPA2 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM10 | c.1436-2A>T p.X479_splice | Splice Site (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- RELN | c.9444-2A>T p.X3148_splice | Splice Site (SNP) | VAF 66/335 reads (20%) | called by muse, mutect2, varscan2
- RIMBP3 | c.2679C>A p.F893L | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RIMS1 | c.2846A>G p.H949R | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RPE65 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SEMA3E | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERPINB3 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLC6A4 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNX5 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- SPTA1 | c.6037C>G p.L2013V | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SST | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ST8SIA1 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- STAB2 | c.4601G>T p.G1534V | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TET2 | c.5725G>T p.E1909* | Nonsense Mutation (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2
- TEX15 | c.1165C>A p.P389T (on ENST00000256246; = p.P772T on NM_001350162.2) | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.382); called by muse, mutect2
- THOC1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS11B | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRPM2 | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- TUSC1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.056); called by muse, varscan2
- WDFY3 | c.6220C>G p.Q2074E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- ZNF335 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF614 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ABCC5 | c.3024A>T p.A1008= | Silent (SNP) | VAF 32/160 reads (20%) | catalogued as COSV55590139; called by muse, mutect2, varscan2
- ARHGAP10 | c.2208G>A p.V736= | Silent (SNP) | VAF 121/259 reads (47%) | called by muse, mutect2, varscan2
- CACNA1E | c.3654C>T p.F1218= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs1310775532; called by muse, mutect2, varscan2
- CBLB | c.192A>G p.K64= | Silent (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- CFAP52 | c.1860C>T p.S620= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1195775715; called by muse, varscan2
- CHKA | c.52C>T p.L18= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- CNTN6 | c.1275G>C p.G425= | Silent (SNP) | VAF 27/191 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2241G>A p.A747= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as rs758102050, COSV100664824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLK1 | c.327C>A p.G109= | Silent (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- DNAH10 | c.7563T>C p.S2521= (on ENST00000409039; = p.S2460= on NM_207437.3) | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- EIF4E1B | c.330C>A p.L110= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- FIBCD1 | c.1365G>C p.R455= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2
- IREB2 | c.2499G>A p.L833= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- KCP | c.2883G>A p.K961= (on ENST00000620378; = p.K1021= on NM_001366122.1) | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as rs774629048, COSV99925796; called by muse, mutect2, varscan2
- KRT6C | c.45C>T p.R15= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as rs777943959; called by muse, mutect2, varscan2
- LRRC49 | c.747C>T p.L249= | Silent (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- MAGED1 | c.882G>T p.V294= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100431815; called by muse, mutect2, varscan2
- MAP1S | c.1089G>T p.A363= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1458602500; called by muse, mutect2, varscan2
- MTRR | c.1710G>T p.V570= (on ENST00000264668; = p.V543= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 96/380 reads (25%) | catalogued as COSV52942344; called by muse, mutect2, varscan2
- MYH6 | c.1635T>C p.T545= | Silent (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- NPAS4 | c.237G>T p.A79= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1405001077; called by muse, mutect2, varscan2
- NPIPA5 | c.789C>A p.L263= | Silent (SNP) | VAF 44/628 reads (7%) | catalogued as COSV64114899; called by muse, mutect2
- OR2A12 | c.669C>A p.A223= | Silent (SNP) | VAF 48/216 reads (22%) | called by muse, mutect2, varscan2
- OR5F1 | c.462G>C p.L154= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV53546439; called by muse, mutect2, varscan2
- OR5V1 | c.441A>T p.S147= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV65830912; called by muse, mutect2, varscan2
- P2RY10 | c.627C>A p.I209= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV50680457; called by muse, mutect2, varscan2
- PDE3A | c.996G>T p.G332= | Silent (SNP) | VAF 49/452 reads (11%) | called by muse, mutect2, varscan2
- POP5 | c.54C>T p.P18= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as rs1227034587; called by muse, mutect2, varscan2
- RBM17 | c.708C>T p.G236= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs1282049090; called by muse, mutect2
- RGPD3 | c.4081A>C p.R1361= | Silent (SNP) | VAF 35/364 reads (10%) | called by muse, mutect2
- RTL1 | c.1533C>A p.V511= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV66017618; called by muse, mutect2, varscan2
- SACM1L | c.12G>T p.A4= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as rs1459914549; called by muse, mutect2, varscan2
- SAMD9 | c.2571C>G p.L857= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- SEMA6A | c.2592C>A p.P864= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs374916648; called by muse, varscan2
- SLC12A6 | c.2367C>T p.L789= (on ENST00000354181 / NM_001365088.1; = p.L738= on NM_005135.2) | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as rs1220512529; called by muse, mutect2
- TMPRSS11B | c.1134C>T p.I378= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV60291725; called by muse, mutect2, varscan2
- TUBA3C | c.300C>A p.A100= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- USP5 | c.12G>C p.L4= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs781933877; called by muse, mutect2, varscan2
- ZNF197 | c.2568G>A p.T856= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs146920588; called by muse, mutect2
- AC023469.1 | n.246G>T | RNA (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- ARSB | c.1213+23257C>T | Intron (SNP) | VAF 54/247 reads (22%) | catalogued as rs773599062; called by muse, mutect2, varscan2
- BMS1P1 | n.850_853del | RNA (DEL) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- CHRAC1 | c.147+291C>T | Intron (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- COL4A2 | c.4139-27A>T | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- EI24P4 | n.1006T>A | RNA (SNP) | VAF 45/216 reads (21%) | called by muse, mutect2, varscan2
- HOXB6 | c.-79+2231G>A | Intron (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- KRTAP2-2 | c.*67A>T | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, varscan2
- MEGF6 | c.482-6846G>C | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, varscan2
- NBPF25P | n.995G>A | RNA (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- NDUFB9 | c.-23G>T | 5'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.631C>T | RNA (SNP) | VAF 12/115 reads (10%) | catalogued as rs775911926; called by muse, mutect2, varscan2
- OR5P1P | n.706C>T | RNA (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2
- PCF11 | c.2092+126C>A | Intron (SNP) | VAF 39/151 reads (26%) | called by muse, mutect2, varscan2
- PDE2A | c.144+6195C>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- PDE4C | c.595+23C>T | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- RNF138 | c.-40C>T | 5'UTR (SNP) | VAF 8/85 reads (9%) | catalogued as rs903699381, COSV99857321; called by muse, mutect2, varscan2
- RNF5P1 | n.302G>T | RNA (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- RPSAP52 | n.791G>C | RNA (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- SLC7A5P2 | n.128G>T | RNA (SNP) | VAF 10/109 reads (9%) | catalogued as rs769117238; called by muse, mutect2, varscan2
- TP53BP1 | c.5290+374A>G | Intron (SNP) | VAF 29/144 reads (20%) | catalogued as rs184671981; called by muse, mutect2, varscan2
- VAPB | c.*1574G>T | 3'UTR (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
